Gene-level copy-number profile of tumor specimen TARGET-20-PASGWH-04A from TARGET case TARGET-20-PASGWH, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 14.4 years (5,251 days).
Specimen TARGET-20-PASGWH-04A: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TARGET-AML.ec99f1ed-e690-5027-8843-9f689de6eded.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TARGET-20-PASGWH-14A (bone marrow normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 389 have no estimate.
https://portal.gdc.cancer.gov/files/e5ce1193-756b-41b8-97d2-a8f93b853f1f

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 11; copy number 1: 2,845; copy number 2: 56,807; copy number 3: 571.

Homozygous deletions (total copy number 0; autosomes only): 11 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:61,581,813–61,642,494, 3 genes: AL935212.3, FAM242D, Y_RNA.
- chr19:42,821,863–42,950,387, 6 genes: PSG8-AS1, PSG10P, PSG1, PSG6, PSG7, CEACAMP7.
- chr19:43,007,656–43,041,248, 2 genes: PSG11, CEACAMP8.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 459. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
